Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACY, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACY-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: HCC

Specimen : liver

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Central hepatectomy

Cholecystectomy

Organ: Liver (15.0 x 11.8 x 6.8 cm, 791.0 gm)

Gallbladder (8.2 cm in length, 3.2 cm in diameter)

Lesion: Huge hepatic mass

- Size: 7.5 x 7.3 x 5.3 cm

- Cut surface: Relatively well-demarcated and encapsulated
yellowish tan, lobulated, solid and extensive necrosis

Gross type: Multinodular confluent

- Extent: Confined to the capsule

Resection margin: Not involved, grossly (safety margin: 0.2 cm)

Remaining parenchyme: Unremarkable

[Gallbladder]

Serosal surface: Yellowish green and smooth

Mucosal surface: Dark green and velvety

Wall: 0.2 cm in thickness

Representative sections are submitted.

Gross photo: Present

Blocks

T1-4, tumor mass of liver x 4

RM, tumor with resection margin x 1

L, nontumorous liver parenchyme x 1

GB, gallbladder x 1

MICROSCOPIC:

Tumor type: Hepatocellular carcinoma

The worst differentiation III

The major differentiation III

Histologic type: Trabecular, tubular, and solid

Cell type: Hepatic

Fatty change: Yes

Cholangiocarcinoma: No

ICD-O-3

Carcinoma, hepatocellular NOS 8170/3

Site: Liver C22.0

QW 5/19/14

[page 2 of 2]
Fibrous capsule formation: Yes
Capsular infiltration: No
Septum formation: Yes
Surgical resection margin invasion: No
Serosal invasion: No
Portal vein invasion: No
Vascular invasion: No
Bile duct invasion: No
Remaining liver parenchyme:
Chronic hepatitis: Yes
Etiology: HBV
Grade, lobular: Mild
Grade, portoperiportal: Mild
Stage (fibrosis): Septal
Cirrhosis: No
Dysplastic nodule: No

NOT reported. Gross:

liver, needle, viral hepatitis

liver,ectomy,hepatocellular carcinoma
T56000, P10, M81703
gallbladder,ectomy,chronic cholecystitis
T57000, P10, M43005

DIAGNOSIS:

Liver, left, central hepatectomy: Hepatocellular carcinoma
Gallbladder, cholecystectomy: Chronic cholecystitis
Suggestion :

Source: NCI Genomic Data Commons file 94f1a58b-06dc-4fce-adb7-13d0bc2e734a (TCGA-DD-AACY.4FB4E64B-1E40-40D8-A90A-ECACC59657E3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).